Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HT, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HT-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Final Diagnosis

- A. TONGUE, RIGHT, GLOSSECTOMY:
High-grade leiomyosarcoma, 4.0 cm in greatest dimension (see comment).
No lymphovascular space invasion identified.
One subglossal lymph node, negative for metastatic carcinoma (0/1)
All final margins are free of tumor (see parts B-G).
Adjacent squamous mucosa with mild dysplasia.
- B. DORSAL TONGUE, EXCISION:
Squamous mucosa, negative for malignancy.
- C. VENTRAL TONGUE MARGIN, EXCISION:
Squamous mucosa, negative for malignancy.
- D. FLOOR OF MOUTH MARGIN, EXCISION:
Squamous mucosa and salivary gland tissue, negative for malignancy.
- E. POSTERIOR TONGUE MARGIN, EXCISION:
Squamous mucosa, salivary gland tissue, and skeletal muscle, negative for malignancy.
- F. DEEP TONGUE POSTERIOR MARGIN, EXCISION:
Skeletal muscle, negative for malignancy.
- G. ANTERIOR DEEP TONGUE, EXCISION:
Skeletal muscle, negative for malignancy.
- H. NECK DISSECTION, RIGHT, LEVELS 2-4:
Forty four lymph nodes, negative for metastatic carcinoma (0/44).
Submandibular gland, free of tumor.
- I. FLOOR OF MOUTH:
Squamous mucosa and underlying salivary gland tissue, skeletal muscle and adipose tissue, free of tumor.
- J. TOOTH, REMOVAL:
Three fragments of teeth (gross diagnosis only).

ICD-O-3

Leiomyosarcoma NOS 8890/3

Site Tongue NOS C02.9

JS 4/22/14

[page 2 of 4]
I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically Signed Out by _____

Comment

Histologic sections of the tumor in the right show a high grade, spindle cell malignancy. Immunohistochemical stains, performed on blocks A4 and A5 with adequate controls, demonstrate the tumor cells to be strongly and diffusely positive for vimentin and desmin, moderately positive for p16, weakly positive for actin, and negative for AE1/AE3, CAM5.2, CK5/6, p63, S-100, CD34, calponin, CD68, myoglobin, pan-melanoma, and smooth-muscle myosin. CD31s shows equivocal staining. These findings support the above diagnosis of a high-grade leiomyosarcoma. Dr. _____ of the sarcoma service and Dr. _____ have reviewed this case and concur.

Specimen(s) Received

- A RIGHT GLOSSECTOMY
- B DORSAL TONGUE FS
- C VENTRAL TONGUE FS
- D FLOOR OF MOUTH FS
- E POSTERIOR TONGUE FS
- F DEEP POSTERIOR TONGUE FS
- G DEEP ANTERIOR TONGUE FS
- H RIGHT NECK DISSECTION LEVEL 2-4
- I RIGHT FLOOR OF MOUTH
- J TOOTH

Clinical History

None given.

Preoperative Diagnosis

Tongue cancer.

Intraoperative Consultation

FSB1. DORSAL TONGUE:

No evidence of malignancy.

FSC1. VENTRAL TONGUE:

No evidence of malignancy.

FSD1. FLOOR OF MOUTH:

Mild dysplasia, no evidence of malignancy.

FSE1. POSTERIOR TONGUE:

No evidence of malignancy.

[page 3 of 4]
FSF1. DEEP POSTERIOR TONGUE:
No evidence of malignancy.

FSG1. DEEP ANTERIOR TONGUE:
No evidence of malignancy.

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr.

I, _____ MD, have performed the intraoperative consultations and issued the above diagnoses.

Gross Description

A. The specimen is received fresh labeled "right glossectomy, double long stitch is posterior floor of mouth, single long stitch is anterior, double short is medial, dorsal tongue". The specimen consists of a right partial glossectomy, which measures 5.0 cm from anterior to posterior, 4.0 cm from dorsal to ventral, and 3.0 cm from medial to lateral. There is an irregular, exophytic, sessile, focally necrotic and hemorrhagic tumor on the mucosa of the tongue, which measures 4.0 x 4.0 x 0.7 cm. The tumor is centrally located and 0.5 cm from the closest anterior aspect of the tongue. All the resection margins of the tongue and floor of mouth are received for frozen section analysis in separate containers. Prior to sectioning, all the aspects of the specimen are inked black. On sectioning, the tumor ranges from 0.7 to 2.0 cm in depth and is 0.2 cm from the closest deep aspect of the specimen. Representative sections of the specimen are submitted to the

Representative sections of the specimen are submitted in 10 cassettes as follows:

- A1: Mirror image of section submitted to the Tissue Procurement Laboratory
- A2-A3: Tumor in relation to closest anterior aspect of the tongue, perpendicular sections
- A4: Tumor in relation to closest posterior aspect of tongue
- A5: Tumor in relation to closest dorsal aspect of tongue
- A6: Tumor in relation to closest ventral aspect of tongue
- A7: Tumor in relation to closest posterior aspect of floor of mouth
- A8-A10: Tumor in relation to closest deep aspect of tongue

B. The specimen is received fresh labeled "dorsal tongue". The specimen consists of an oblong fragment of pink tan, rubbery tissue partially covered with mucosa. The specimen measures 2.5 x 0.5 x 0.2 cm. No tissue is submitted to the _____ The specimen is submitted entirely for frozen section as FSB1.

C. The specimen is received fresh labeled "ventral tongue margin". The specimen consists of an oblong fragment of tan pink to red, rubbery tissue partially covered with mucosa. The specimen measures 3.0 x 0.5 x 0.2 cm and is submitted entirely for frozen section as FSC1. No tissue is submitted to the

D. The specimen is received fresh labeled "floor of mouth margin". The specimen consists of an oblong fragment of pink tan tissue partially covered by mucosa. The specimen measures 2.5 x 0.5 x 0.2 cm and is submitted entirely for frozen section as FSD1. No tissue is submitted to the

E. The specimen is received fresh labeled "posterior tongue margin". The specimen consists of

[page 4 of 4]
an oblong fragment of pink tan, rubbery tissue partially covered with mucosa. The specimen measures 2.0 x 0.5 x 0.2 cm and is submitted entirely for frozen section as FSE1. No tissue is submitted to the

F. The specimen is received fresh labeled "deep tongue posterior margin". The specimen consists of an irregular fragment of tan red to brown, rubbery tissue measuring 2.0 x 1.5 x 0.2 cm. No tissue is submitted to the . The specimen is entirely submitted for frozen section as FSF1.

G. The specimen is received fresh labeled "anterior deep tongue". The specimen consists of an irregular fragment of tan red brown, rubbery tissue measuring 1.5 x 1.5 x 0.2 cm. No tissue is submitted to the . The specimen is entirely submitted for frozen section as FSG1.

H. The specimen is labeled "right neck dissection 2-4, double stitch marks level 4, single stitch level 2." The specimen consists of a submandibular gland (3.5 x 2.5 x 1.5 cm) with a large amount of fibroadipose tissue attached. The specimen measures in overall dimension 11 x 4 x 2 cm. The specimen is oriented according to the surgeon designation and is divided into 4 levels, 1-4. The submandibular gland is serially sectioned to reveal grossly unremarkable pink-tan, lobulated cut surface. No sternocleidomastoid muscle or internal jugular vein is identified. The specimen is oriented according to the surgeon designation and is divided into 4 levels, 1-4. On sectioning, the fibroadipose tissue of the level 1-4 multiple potential lymph nodes are grossly identified, which range from 0.1 to 1.7 cm in greatest dimension. No tissue is submitted to the

Representative sections of the specimen are submitted in 20 cassettes as follows:

- H1: Submandibular gland.
- H2: Two lymph nodes, level 1.
- H3: Three lymph nodes level 1.
- H4: One lymph node, level 2.
- H5: Three lymph nodes, level 2.
- H6: One lymph node, level 2.
- H7: One lymph node, level 2.
- H8: Two lymph nodes, level 2.
- H9: One lymph node, level 2.
- H10: One lymph node, level 3.
- H11: One lymph node, level 3.
- H12-H14: Nine lymph nodes, level 3, 3 lymph nodes per cassette.
- H15: Four lymph nodes, level 3.
- H16: Three lymph nodes, level 3.
- H17-H20: Twelve lymph nodes, level 4, 3 lymph nodes per cassette.

I. The specimen is received fresh labeled "right floor of mouth". The specimen consists of an irregular to oblong, unoriented fragment of tan red brown, rubbery tissue, which is partially covered by mucosa. The specimen measures 4.5 x 1.8 x 0.7 cm. The specimen has not been oriented by the surgeon and all the resection margins are inked black. No tissue is submitted to the

The specimen is serially sectioned and is submitted entirely in 6 cassettes, I1-I6.

J. The specimen is labeled "tooth." The specimen consists of 3 fragments of teeth, which are ranging from 0.7 to 1.3 cm in greatest dimension. The fragments consistent with teeth roots. One tooth also contains an irregular fragment of crown. No tissue is submitted to the

The specimen is received for gross analysis only.

Source: NCI Genomic Data Commons file 466f3bbf-e5e9-4e24-a2ef-c32308cc0fe8 (TCGA-3B-A9HT.1978D473-CA80-4C15-A155-370D9EE56784.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).